Somatic mutation profile of tumor specimen C3N-05623-01 (aliquot CPT0322580007) from CPTAC case C3N-05623, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 57.0 years (20,821 days).
Specimen C3N-05623-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 307a9ef2-b8fa-49ed-bb47-cf339150083b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-05623-31 (Blood Derived Normal), aliquot CPT0322640002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b525b20-36b2-46c8-b35a-528015d3ad43

The open-access MAF lists 128 somatic variants for this specimen: 86 protein-altering or splice-affecting, 40 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 40, Nonsense Mutation 6, In Frame Del 2, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 151/372 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCA8 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 104/359 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.052); catalogued as rs143566631; called by muse, mutect2, varscan2
- ASPG | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 133/472 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.214); catalogued as rs1197683204; called by muse, mutect2, varscan2
- C3orf20 | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 93/369 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.366); catalogued as COSV53783581; called by muse, mutect2, varscan2
- CCER1 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 170/523 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV100727100, COSV62647956; called by muse, mutect2, varscan2
- CDH7 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 163/504 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775706781, COSV59884116; called by muse, mutect2, varscan2
- CEP128 | c.2804G>A p.R935K | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV55389566; called by muse, mutect2, varscan2
- CES1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 126/767 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs746693909, COSV62089827; called by muse, varscan2
- CSMD1 | c.1237G>A p.G413R (on ENST00000520002; = p.G412R on NM_033225.6) | Missense Mutation (SNP) | VAF 96/251 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758625595; called by muse, varscan2
- DEFB125 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 109/445 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.161); catalogued as COSV66703111; called by muse, mutect2, varscan2
- DNAH5 | c.9928C>T p.R3310C | Missense Mutation (SNP) | VAF 122/384 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs900076362, COSV54204182; called by muse, mutect2, varscan2
- DPP10 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 177/317 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs1278855062, COSV59687953; called by muse, mutect2, varscan2
- EPHA6 | c.2210G>A p.G737E (on ENST00000389672 / NM_001080448.3; = p.G129E on NM_173655.4) | Missense Mutation (SNP) | VAF 62/229 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768752127; called by muse, mutect2, varscan2
- FLRT2 | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 123/392 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs149450183; called by muse, mutect2, varscan2
- GABBR2 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 130/410 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52301701; called by muse, mutect2, varscan2
- HJV | c.1000C>T p.R334C (on ENST00000336751 / NM_213653.4; = p.R221C on NM_145277.5) | Missense Mutation (SNP) | VAF 178/559 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.828); catalogued as COSV60952719, COSV60952952; called by muse, mutect2, varscan2
- LRRC30 | c.786G>A p.W262* | Nonsense Mutation (SNP) | VAF 130/465 reads (28%) | catalogued as COSV67302362; called by muse, mutect2, varscan2
- MAGEC3 | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 68/119 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as rs868755424, COSV100025455; called by muse, mutect2, varscan2
- MTF1 | c.1864C>T p.P622S | Missense Mutation (SNP) | VAF 82/313 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65989804; called by muse, mutect2, varscan2
- MYH6 | c.5089A>G p.T1697A | Missense Mutation (SNP) | VAF 145/478 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.257); catalogued as rs727503233; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBN | c.1618C>T p.H540Y | Missense Mutation (SNP) | VAF 167/396 reads (42%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs1554558393, COSV55374312, COSV55377442; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NES | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 100/409 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as rs762007164; called by muse, mutect2, varscan2
- OR10H4 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 93/367 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs762794061, COSV59062597; called by muse, mutect2, varscan2
- OR13J1 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 112/352 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs749283534; called by muse, mutect2, varscan2
- PCM1 | c.3538C>T p.P1180S | Missense Mutation (SNP) | VAF 89/415 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767341755; called by muse, mutect2, varscan2
- PRAMEF6 | c.502C>A p.L168I | Missense Mutation (SNP) | VAF 105/549 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.117); catalogued as rs1325736799, COSV61910645; called by muse, mutect2, varscan2
- RBPJL | c.1302C>A p.C434* | Nonsense Mutation (SNP) | VAF 118/426 reads (28%) | catalogued as rs1333952891, COSV100643481, COSV59212787; called by muse, mutect2, varscan2
- RYR1 | c.12766G>T p.E4256* | Nonsense Mutation (SNP) | VAF 135/464 reads (29%) | catalogued as rs770517037; called by muse, mutect2, varscan2
- RYR2 | c.9908C>T p.S3303F | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV100773357; called by muse, mutect2, varscan2
- RYR3 | c.13331T>C p.V4444A (on ENST00000389232; = p.V4445A on NM_001036.6) | Missense Mutation (SNP) | VAF 105/362 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV101211698; called by muse, mutect2, varscan2
- SAMD3 | c.662G>A p.W221* | Nonsense Mutation (SNP) | VAF 60/182 reads (33%) | catalogued as rs147217519, COSV63718311; called by muse, mutect2, varscan2
- SCN9A | c.3163G>A p.E1055K (on ENST00000303354; = p.E1044K on NM_002977.3) | Missense Mutation (SNP) | VAF 265/444 reads (60%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV57619461; called by muse, mutect2, varscan2
- SGCD | c.836C>T p.S279F (on ENST00000435422 / NM_001128209.2; = p.S280F on NM_000337.5) | Missense Mutation (SNP) | VAF 86/309 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs397516337; called by muse, mutect2, varscan2
- SKA3 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 66/285 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53436061; called by muse, mutect2, varscan2
- SLC26A2 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 115/422 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs374254724; called by muse, mutect2, varscan2
- SLC38A4 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 88/322 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56968003; called by muse, mutect2, varscan2
- TFAP2C | c.1313C>T p.S438F | Missense Mutation (SNP) | VAF 111/398 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs1454624343; called by muse, mutect2, varscan2
- TNFRSF10D | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 108/485 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.166); catalogued as rs148603893; called by muse, mutect2, varscan2
- TRANK1 | c.4657C>T p.P1553S | Missense Mutation (SNP) | VAF 112/422 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1157435873, COSV57163722; called by muse, mutect2, varscan2
- UBE2Q2 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 52/255 reads (20%) | catalogued as COSV51196923; called by muse, mutect2, varscan2
- ADAM33 | c.1982G>A p.G661E | Missense Mutation (SNP) | VAF 131/424 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAM7 | c.544G>T p.G182W | Missense Mutation (SNP) | VAF 153/411 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- ADH1C | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 68/280 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANK2 | c.8821G>A p.E2941K | Missense Mutation (SNP) | VAF 112/392 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- BBS9 | c.2196T>A p.H732Q (on ENST00000242067 / NM_001348036.1; = p.H692Q on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 264/567 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CAMSAP2 | c.1814A>C p.D605A (on ENST00000236925 / NM_001297707.2; = p.D594A on NM_203459.3) | Missense Mutation (SNP) | VAF 101/332 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- CCIN | c.1016T>A p.I339N | Missense Mutation (SNP) | VAF 115/457 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CDC20 | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 114/386 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CFAP54 | c.9253G>A p.G3085R | Missense Mutation (SNP) | VAF 65/298 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- CHRNA2 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 81/389 reads (21%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- DHRSX | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 163/382 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DOP1A | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 85/215 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- FABP12 | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 66/425 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- FEZF2 | c.676T>C p.F226L | Missense Mutation (SNP) | VAF 161/528 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- GTF2IRD2 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 82/376 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HELQ | c.437A>G p.E146G | Missense Mutation (SNP) | VAF 101/381 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IRF2BPL | c.1748C>A p.A583D | Missense Mutation (SNP) | VAF 142/507 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- KCNQ3 | c.2438G>A p.R813K | Missense Mutation (SNP) | VAF 494/1085 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA1586 | c.1179_1196del p.N393_R398del | In Frame Del (DEL) | VAF 102/319 reads (32%) | called by mutect2, pindel, varscan2
- LRRC31 | c.49C>A p.Q17K | Missense Mutation (SNP) | VAF 84/309 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by mutect2, varscan2
- MAG | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 161/556 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- MCF2L2 | c.1270G>T p.G424* | Nonsense Mutation (SNP) | VAF 52/232 reads (22%) | called by mutect2, varscan2
- MEGF10 | c.2461C>T p.P821S | Missense Mutation (SNP) | VAF 74/267 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- MYH15 | c.581T>C p.F194S | Missense Mutation (SNP) | VAF 59/250 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- NBN | c.653_655del p.R218del | In Frame Del (DEL) | VAF 35/270 reads (13%) | called by mutect2, pindel, varscan2
- NKX3-1 | c.473C>G p.A158G | Missense Mutation (SNP) | VAF 187/498 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCH1 | c.4666G>C p.D1556H (on ENST00000340059 / NM_001130960.2; = p.D1548H on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 126/414 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLXNA4 | c.2414G>A p.G805E | Missense Mutation (SNP) | VAF 84/463 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RACK1 | c.379A>G p.K127E | Missense Mutation (SNP) | VAF 114/391 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RALGAPA1 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM25 | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 114/445 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RGS3 | c.3272T>C p.L1091P (on ENST00000350696 / NM_001282923.2; = p.L810P on NM_130795.4) | Missense Mutation (SNP) | VAF 93/352 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RXFP1 | c.776T>A p.I259N | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SACS | c.5950A>T p.T1984S | Missense Mutation (SNP) | VAF 91/472 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNTA1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 90/373 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- SPESP1 | c.227A>C p.E76A | Missense Mutation (SNP) | VAF 112/396 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- SYCP2L | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- TENM2 | c.7735G>T p.G2579W (on ENST00000518659 / NM_001122679.2; = p.G2340W on NM_001080428.3) | Missense Mutation (SNP) | VAF 154/492 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TFAP2C | c.1312T>A p.S438T | Missense Mutation (SNP) | VAF 112/401 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP17L1 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- WDR31 | c.563G>A p.R188K (on ENST00000374193 / NM_001006615.3; = p.R187K on NM_145241.5) | Missense Mutation (SNP) | VAF 67/261 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WIF1 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 92/364 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); called by muse, mutect2
- ZBTB22 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 360/842 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB34 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 148/505 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF236 | c.4319G>A p.G1440D | Missense Mutation (SNP) | VAF 125/413 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- ZNF557 | c.152C>T p.A51V (on ENST00000414706 / NM_001044388.2; = p.A58V on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/492 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ANKRD44 | c.1122C>T p.F374= | Silent (SNP) | VAF 179/301 reads (59%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.1815G>A p.R605= | Silent (SNP) | VAF 234/386 reads (61%) | called by muse, mutect2, varscan2
- BTN2A1 | c.1072C>T p.L358= | Silent (SNP) | VAF 154/615 reads (25%) | catalogued as rs753532528; called by muse, mutect2, varscan2
- CACNA1H | c.3543C>T p.D1181= | Silent (SNP) | VAF 67/628 reads (11%) | catalogued as rs958144782, COSV61987153; called by muse, mutect2, varscan2
- CACNA2D3 | c.1557G>A p.G519= | Silent (SNP) | VAF 74/246 reads (30%) | catalogued as rs531747910; called by muse, mutect2, varscan2
- CASP12 | c.732C>T p.L244= | Silent (SNP) | VAF 119/402 reads (30%) | called by muse, mutect2, varscan2
- CEP170B | c.1023C>T p.S341= (on ENST00000453495; = p.S270= on NM_015005.3) | Silent (SNP) | VAF 92/329 reads (28%) | catalogued as rs745569602; called by muse, varscan2
- CPSF1 | c.2583C>T p.P861= | Silent (SNP) | VAF 346/726 reads (48%) | called by muse, mutect2, varscan2
- FAM221B | c.291C>A p.P97= | Silent (SNP) | VAF 72/322 reads (22%) | called by muse, mutect2, varscan2
- GABBR1 | c.1716C>T p.S572= | Silent (SNP) | VAF 102/535 reads (19%) | catalogued as rs549986688; called by muse, mutect2, varscan2
- GIPC3 | c.2886C>T p.I962= | Silent (SNP) | VAF 59/186 reads (32%) | catalogued as rs983425170; called by muse, mutect2, varscan2
- GUCY2F | c.2361G>A p.L787= | Silent (SNP) | VAF 144/307 reads (47%) | called by muse, mutect2, varscan2
- HPX | c.1116C>T p.L372= | Silent (SNP) | VAF 88/337 reads (26%) | catalogued as COSV56420352; called by muse, mutect2, varscan2
- HYDIN | c.15120C>T p.I5040= | Silent (SNP) | VAF 141/509 reads (28%) | catalogued as COSV101124821; called by muse, mutect2, varscan2
- KLHL17 | c.438G>A p.L146= | Silent (SNP) | VAF 109/400 reads (27%) | catalogued as rs373209389; called by muse, mutect2, varscan2
- LILRB2 | c.1176G>A p.G392= | Silent (SNP) | VAF 174/659 reads (26%) | called by muse, mutect2, varscan2
- MYL7 | c.264C>G p.T88= | Silent (SNP) | VAF 187/500 reads (37%) | catalogued as COSV56268555; called by muse, mutect2, varscan2
- MYT1L | c.2889C>T p.I963= | Silent (SNP) | VAF 231/423 reads (55%) | catalogued as rs1052642314; called by muse, mutect2, varscan2
- NEK6 | c.807C>T p.L269= | Silent (SNP) | VAF 64/289 reads (22%) | catalogued as COSV57217922; called by muse, mutect2, varscan2
- NEURL1 | c.1503G>A p.S501= | Silent (SNP) | VAF 80/211 reads (38%) | catalogued as rs138244046; called by muse, mutect2, varscan2
- NUP54 | c.438C>T p.A146= | Silent (SNP) | VAF 107/374 reads (29%) | called by muse, mutect2, varscan2
- OR10H4 | c.417C>T p.P139= | Silent (SNP) | VAF 93/368 reads (25%) | called by muse, mutect2, varscan2
- OR11L1 | c.619C>T p.L207= | Silent (SNP) | VAF 135/429 reads (31%) | catalogued as rs1441820778; called by muse, mutect2, varscan2
- PCDHB2 | c.2319C>T p.I773= | Silent (SNP) | VAF 80/324 reads (25%) | catalogued as COSV50575112; called by muse, mutect2, varscan2
- PCSK2 | c.495T>C p.I165= | Silent (SNP) | VAF 68/263 reads (26%) | called by muse, mutect2, varscan2
- PDCD6 | c.201G>A p.S67= | Silent (SNP) | VAF 35/191 reads (18%) | catalogued as rs1438063229; called by muse, mutect2, varscan2
- PLCL1 | c.1497G>A p.Q499= | Silent (SNP) | VAF 253/456 reads (55%) | called by muse, mutect2, varscan2
- PLOD2 | c.387C>T p.F129= | Silent (SNP) | VAF 123/419 reads (29%) | catalogued as COSV51469092; called by muse, mutect2, varscan2
- PRPF31 | c.582G>A p.A194= | Silent (SNP) | VAF 174/634 reads (27%) | catalogued as rs757374570; called by muse, mutect2, varscan2
- RPS28 | c.195C>T p.A65= | Silent (SNP) | VAF 86/283 reads (30%) | catalogued as rs754819226; called by muse, mutect2, varscan2
- SERPING1 | c.855C>T p.T285= | Silent (SNP) | VAF 107/371 reads (29%) | catalogued as CD020872; called by muse, mutect2, varscan2
- SETBP1 | c.348C>T p.P116= | Silent (SNP) | VAF 107/390 reads (27%) | catalogued as rs766352727; called by muse, mutect2, varscan2
- SLC12A8 | c.1815C>T p.S605= | Silent (SNP) | VAF 65/262 reads (25%) | catalogued as rs375379599; called by muse, mutect2, varscan2
- SNAP91 | c.1902T>C p.D634= | Silent (SNP) | VAF 110/277 reads (40%) | called by muse, mutect2, varscan2
- SNUPN | c.972C>T p.L324= | Silent (SNP) | VAF 119/425 reads (28%) | catalogued as rs769707280; called by muse, mutect2, varscan2
- SOCS7 | c.954T>C p.S318= | Silent (SNP) | VAF 143/518 reads (28%) | catalogued as rs1320502705; called by muse, mutect2, varscan2
- SPEF2 | c.237G>A p.Q79= | Silent (SNP) | VAF 137/467 reads (29%) | called by muse, mutect2, varscan2
- TRAV27 | c.9G>A p.L3= | Silent (SNP) | VAF 100/330 reads (30%) | catalogued as rs1226013799; called by muse, mutect2, varscan2
- ZHX2 | c.474C>T p.T158= | Silent (SNP) | VAF 341/810 reads (42%) | catalogued as rs768200301, COSV58710746; called by muse, mutect2, varscan2
- ZNF99 | c.90G>A p.R30= | Silent (SNP) | VAF 46/136 reads (34%) | called by muse, mutect2, varscan2
- IL4I1 | chr19:49901658 G>A | 5'Flank (SNP) | VAF 101/392 reads (26%) | called by muse, mutect2, varscan2
- ZNF783 | c.802+3093G>T | Intron (SNP) | VAF 322/738 reads (44%) | called by muse, mutect2, varscan2
